Surgical pathology report (de-identified scan), TCGA case TCGA-24-1466, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-1466-01A (Primary Tumor).

[page 1 of 4]
Patient Name:

DOB:

Surgical Pathology Report

Final

Patient Name:	SURGICAL PATHOLOGY REPORT	
Address:	M.	
Gender:	Service	Accession #:
DOB:	Location	Taken:
Physician(s):	MRN:	Received:
	Hospital	Reported
	Patient Typ	

Other Related Clinical Data:

DIAGNOSIS: OVARIES, RIGHT AND LEFT, BILATERAL SALPINGO-OOPHORECTOMY AND FS1
- PAPILLARY SEROUS ADENOCARCINOMA, POORLY DIFFERENTIATED WITH SURFACE INVOLVEMENT

SOFT TISSUE, LEFT PAROVARIAN , EXCISION
- PAPILLARY SEROUS ADENOCARCINOMA

FALLOPIAN TUBES, RIGHT AND LEFT, BILATERAL SALPINGO-OOPHORECTOMY
- FREE FLOATING LUMINAL TUMOR CLUSTERS

UTERUS, SEROSA, ABDOMINAL HYSTERECTOMY
- PAPILLARY SEROUS ADENOCARCINOMA

SOFT TISSUE, SMALL BOWEL SEROSA, BIOPSY
- FIBROUS ADHESION WITH METASTATIC PAPILLARY SEROUS ADENOCARCINOMA

OMENTUM, EXCISION
- PAPILLARY SEROUS ADENOCARCINOMA, METASTATIC

UTERUS, CERVIX, ABDOMINAL HYSTERECTOMY
- NO HISTOPATHOLOGIC ABNORMALITIES

UTERUS, ENDOMETRIUM, ABDOMINAL HYSTERECTOMY
- ATROPHIC WITH FOCAL MUCINOUS AND CILIATED METAPLASIA
- SESSILE ENDOMETRIAL POLYP

UTERUS, MYOMETRIUM, ABDOMINAL HYSTERECTOMY
- NO HISTOPATHOLOGIC ABNORMALITIES

[page 2 of 4]
Patient Name:

DOB:

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

***Report Electronically Reviewed and Signed Out By

Intraoperative Consultation: An intraoperative microscopic consultation was obtained and interpreted as: #1. "Called to O.R. to pick up 10.5 x 9.0 x 6.0 cm right adnexa with attached 6.5 x 0.75 cm fallopian tube. The cystic adnexa is punctured to show extrusion of serosanguineous fluid. The wall contains solid, sessile nodular mass that measures 4.0 x 3.5 cm in maximum dimension. Sections of the mass are submitted for frozen section and taken for tumor repository," by

#2. "Called to O.R. to pick up uterus that measures 3.5 cm from superior to inferior surfaces, 3.0 cm from cornu to cornu, and 1.7 cm from the anterior to posterior serosal surface. The external surface is unremarkable. The cervix measures 3.0 x 3.0 cm and opened coronally to show unremarkable endocervical canal and small firm 0.5 cm nodule at the endocervical endometrial junction. Suspicious for hyperplasia. All for permanents," by

FS: Adnexa, right, oophorectomy - "Adenocarcinoma, Mullerian origin,"

Microscopic Description and Comment: Both right and left ovaries are largely replaced by poorly differentiated papillary serous adenocarcinoma. The tumor involves the surfaces of both ovaries and extends along the parovarian soft tissue on the left. Free floating clusters of tumor cells are identified in the lumina of the right and left fallopian tubes. The tumor also involves the serosal surface of the uterus, the small bowel fibrous adhesion, and the omentum. There are no significant histopathologic abnormalities in the cervix. The endometrium is atrophic with focal mucinous and ciliated metaplasia. There is a sessile endometrial polyp. There are no significant histopathologic abnormalities in the myometrium.

History: The patient is a year old woman with bilateral adnexal masses and "spread pattern" consistent with ovarian primary tumor.

Specimen(s) Received:

- A: RIGHT ADNEXA
- B: LEFT ADNEXA
- C: HYSTERECTOMY, BSO
- D: SMALL BOWEL ADEHISION
- E: OMENTUM BIOPSY

Gross Description The specimens are received in five containers of formalin, each labelled with the patient's name. The first container is labeled "right adnexa - FS, X" and contains a previously opened unilocular cystic ovary that measures 10.5 x 9.0 x 6.0 cm. The surface is blue-grey and diffusely covered by tan-white nodules that measure 1.5 cm in greatest dimension. The cyst wall is remarkable for a firm nodular and papillary region that measures 4.5 x 3.0 cm. There is an attached fallopian tube that measures 6.5 cm in length and 0.5 cm in average diameter. The surface is remarkable for multiple tan-yellow, nodular and cystic areas that measure 0.4 cm in greatest dimension. The solid portion of the ovarian cyst is sectioned to show a tan-white, focally hemorrhagic and friable tumor that appears to extend into the paraovarian tissue and involve the ovarian surface. Cut section of the fallopian tube shows no grossly suspicious masses or papillary excrescences. Also included is a white cassette (frozen section) that contains two tan-white and yellow friable fragments of tissue that measure 1.0 x 0.6 x 0.2 cm each. Labeled: A1 to A3 - sections of largest solid

[page 3 of 4]
Patient Name:

DOB:

component of ovarian tumor with possible surface involvement in A3; A4 - sections of smaller nodules with probable surface involvement; A5 - sections of fallopian tube with including small unilocular cysts on serosal surface; A6 - FS sections of tissue submitted for frozen section. Jar 2.

The second container is labeled "left adnexa." It contains a cystic ovary that measures 6.5 x 6.0 x 4.0 cm. The surface of the ovary is remarkable for multiple tan-white nodules that measure 0.5 cm in greatest dimension. The ovary is opened to show a unilocular cyst with a rugated appearing surface with small foci of papillary excrescences, the largest measuring 0.5 cm in greatest dimension. There is a solid area that measures 4.5 x 4.0 cm. The attached fallopian tube measures 6.0 cm in length and 0.7 cm in average diameter. The serosal surface shows multiple tan-yellow, cystic-appearing structures. Cut section of the fallopian tube shows no grossly suspicious masses or papillary excrescences. Additional cut section of the solid component of the ovarian tumor shows possible involvement of surrounding paraovarian soft tissue.

Labeled: B1 to B3 - sections of ovarian tumor with possible soft tissue involvement in section B3; B4 - sections of nodules that stud the ovarian serosal surface; B5 - sections of left fallopian tube. Jar 2.

The third container is labeled "uterus and cervix." It contains a uterus that measures 6.0 cm from the fundus to the cervix, 3.5 cm from the left to the right cornu, 2.0 cm, from the anterior to posterior serosal surface and weighs 35 grams. The serosal surface is focally hemorrhagic, but shows no grossly suspicious lesions. The cervix measures 2.5 x 2.5 cm and shows a tan-white creamy unremarkable mucosal surface. A centrally located slit-like os measures 0.4 cm in maximum dimension. The uterus is bivalved to show an endocervical canal that measures 1.7 cm in length and 0.3 cm in average diameter. The endocervical mucosa is grossly unremarkable. The endometrial cavity measures 2.0 x 0.5 x 0.5 cm. There is a firm nodule on the posterior endometrial surface that measures 0.5 cm in greatest dimension. The endometrial surface is otherwise tan-white, smooth and grossly unremarkable. Cut section of the nodule and the uterine wall shows no grossly suspicious masses. The uterine wall measures 0.7 cm in maximum thickness. Labeled: C1 - section of anterior cervix; C2 section of posterior cervix; C3 and C4 - sections of entirely submitted anterior endometrial surface and underlying myometrium; C5 to C8 - sections of entirely submitted posterior endometrial surface and underlying myometrium. Jar 2.

The fourth container is labeled "small bowel adhesion" and contains a tan-white tubular shaped fragment of adipose and tan-white soft tissue. Cut section shows no grossly suspicious lesions. Labeled D1. Jar 0.

The fifth container is labeled "omentum" and contains a tan-yellow and brown segment of adipose tissue that measures 28.0 x 7.0 x 1.5 cm. A firm mass is palpated that measures 7.0 cm in maximum dimension. Multiple smaller nodules are also palpable within the fragment of omental tissue. Serial section shows tan-white tissue grossly suspicious from metastatic carcinoma. Labeled: E1 - section of omental nodule. Jar 2.

Synopsis SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS 1. A neoplasm is PRESENT 2. The HISTOLOGIC DIAGNOSIS is: Serous adenocarcinoma 3. The LOCATION(S) OF THE PRIMARY TUMOR(S) is/are: Right and left ovary 4. The FIGO GRADE of the tumor is: III 5. Tumor IS identified on the ovarian surface(s). 6. Tumor DOES involve the mesovarium. 7. Tumor DOES NOT invade the adjacent fallopian tube. 10. Metastatic involvement of the EXTRAPELVIC PERITONEUM is PRESENT. 11. Metastatic involvement of the omentum is PRESENT. 12. The maximum dimension of tumor implants outside the true pelvis is 7 cm 13. Metastatic

[page 4 of 4]
Patient Name:

DOB:

involvement of the uterine serosa is PRESENT. 14. Metastatic involvement of the endometrium is ABSENT. 15. Regional lymph node metastases CANNOT BE EVALUATED. 16. DETAILED STAGING INFORMATION:

Based on the above information, the PRIMARY TUMOR is classified as:

TNM Scheme	FIGO Scheme	Definition
T3c	IIIC	Macroscopic peritoneal
metastasis beyond true pelvis measuring > 2 cm in greatest dimension,		
THE REGIONAL LYMPH NODES are classified as: NX (Nodal status cannot be assessed)		
THE STATUS OF DISTANT TUMOR SITES is classified as: MX (Status cannot be assessed) 17. The		
FINAL AJCC/FIGO STAGE IS:		

AJCC Scheme

FIGO Scheme

X

Insufficient data to assign stage

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

Source: NCI Genomic Data Commons file 7a13dfae-462e-46ca-a0f4-f2d664e80311 (TCGA-24-1466.BA86880B-184B-4CB7-8BBF-100D5CBD76C0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).